Somatic mutation profile of tumor specimen TCGA-D1-A167-01A (aliquot TCGA-D1-A167-01A-11D-A12J-09) from TCGA case TCGA-D1-A167, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 70.0 years (25,575 days).
Specimen TCGA-D1-A167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f26f5e4-6e4f-48ba-abec-3b7b6bbe9243.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A167-10A (Blood Derived Normal), aliquot TCGA-D1-A167-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62f41d03-4148-4a7e-b150-63685353eac3

The open-access MAF lists 1,950 somatic variants for this specimen: 1,390 protein-altering or splice-affecting, 520 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,193, Silent 520, Nonsense Mutation 86, Frame Shift Del 57, Frame Shift Ins 19, Intron 18, Splice Site 16, Splice Region 15, RNA 8, 3'Flank 5, 3'UTR 4, In Frame Del 3.

Variants (750 of 1,950; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123503, CM097509, COSV54199677; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACVR1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912679, CM080031, COSV55117476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C19orf12 | c.157G>A p.G53R (on ENST00000392278 / NM_001031726.3; = p.G42R on NM_031448.6) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200133991, CM118378, COSV60365206; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 62/117 reads (53%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DEPDC5 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as rs1568991466, COSV56707538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 103/236 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HARS2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 137/335 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs140540222; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- HDAC8 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1556007534, COSV65238122; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HR | c.3034G>A p.D1012N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs121434451, CM022964, COSV100456019; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs727503093, COSV54244375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH3 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913618, CM061868, COSV56869681; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- STAT3 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113994139, CM076546, CM077977, COSV52888942; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); catalogued as COSV55298126; called by muse, mutect2, varscan2
- AAK1 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs1032607711, COSV101117268; called by muse, mutect2
- AAK1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68646506; called by muse, mutect2, varscan2
- AAR2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs1356008286, COSV57924914; called by muse, varscan2
- AASS | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as rs560418184, COSV62791646; called by muse, mutect2, varscan2
- ABCB8 | c.823C>T p.R275* (on ENST00000297504 / NM_001282291.2; = p.R258* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs369818772; called by muse, mutect2, varscan2
- ABCG4 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV56645636; called by muse, mutect2, varscan2
- ABR | c.2201C>T p.T734M (on ENST00000302538 / NM_021962.5; = p.T697M on NM_001092.5) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52148796; called by muse, mutect2, varscan2
- ABR | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs765186007, COSV56843101; called by muse, mutect2, varscan2
- ABTB1 | c.1184G>A p.R395Q (on ENST00000232744 / NM_172027.3; = p.R253Q on NM_032548.3) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs142290721; called by muse, mutect2, varscan2
- AC068580.4 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs373170074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAP1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs748247131, COSV50134664; called by muse, mutect2, varscan2
- ACER1 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as rs1024929658, COSV56834790; called by muse, mutect2
- ACLY | c.3191G>A p.G1064E | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV59863051; called by muse, varscan2
- ACO1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199823143, COSV59378955; called by muse, mutect2, varscan2
- ACOX2 | c.1454G>A p.C485Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV57150724; called by muse, mutect2, varscan2
- ACOX3 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.166); catalogued as rs780165236, COSV62713115; called by muse, mutect2, varscan2
- ACSL3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as rs376738660; called by muse, mutect2, varscan2
- ACTL7B | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV65928115; called by muse, mutect2, varscan2
- ACTR5 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs745886967, COSV54762155; called by muse, mutect2, varscan2
- ACVRL1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746197083, COSV66359467, COSV66361012; called by muse, mutect2, varscan2
- ADAM23 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 263/274 reads (96%) | catalogued as COSV52224855, COSV52229021; called by muse, mutect2, varscan2
- ADAM29 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746641739, COSV63663321; called by muse, mutect2, varscan2
- ADAMTS2 | c.3250G>T p.G1084C | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52391857; called by muse, mutect2, varscan2
- ADAMTS2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781106942, COSV99204723; called by muse, mutect2
- ADAMTSL4 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs587666522, COSV55007095; called by muse, mutect2, varscan2
- ADCY3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs772293701, COSV53172390; called by muse, mutect2, varscan2
- ADGRE5 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs754719568, COSV54414576; called by muse, mutect2, varscan2
- ADGRF1 | c.2655C>A p.N885K | Missense Mutation (SNP) | VAF 63/652 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99347591; called by muse, mutect2
- ADGRF3 | c.2782A>G p.T928A (on ENST00000311519 / NM_001145168.1; = p.T729A on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV61053083; called by muse, mutect2, varscan2
- ADNP | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62426826; called by muse, mutect2, varscan2
- ADRA1A | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.692); catalogued as COSV52362466; called by muse, mutect2, varscan2
- ADSL | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53406975; called by muse, mutect2, varscan2
- AFF3 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1304982504, COSV57862515; called by muse, mutect2, varscan2
- AFF3 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as rs771477461, COSV57871951; called by muse, mutect2, varscan2
- AFF3 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1383264450, COSV57856962, COSV57870376; called by muse, mutect2, varscan2
- AGAP2 | c.1975G>A p.E659K (on ENST00000547588 / NM_001122772.2; = p.E323K on NM_014770.4) | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs772641164, COSV57728061; called by muse, mutect2, varscan2
- AGO2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99596340; called by muse, mutect2
- AKAP17A | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs199716339, COSV58311881; called by muse, mutect2, varscan2
- AKAP4 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 152/316 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1293034315, COSV62075411; called by muse, mutect2, varscan2
- ALDH18A1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760203992, COSV100973326, COSV64663580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs769522277, COSV51090735; called by muse, mutect2, varscan2
- ALDH1A3 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199537142; called by muse, mutect2, varscan2
- ALDH1L1 | c.1900G>A p.G634S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1159245188, COSV56414682; called by muse, mutect2, varscan2
- ALG13 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1244741380, COSV52644807; called by muse, mutect2, varscan2
- ALG8 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs763258107, COSV55201130; called by muse, mutect2, varscan2
- ALPK1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188866014; called by muse, mutect2, varscan2
- ALPK3 | c.4015G>A p.V1339I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs756951762, COSV51932784; called by muse, mutect2, varscan2
- ALYREF | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1381337363, COSV58669133; called by muse, mutect2, varscan2
- AMBRA1 | c.2272T>A p.S758T (on ENST00000458649 / NM_001367468.1; = p.S668T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.115); catalogued as rs748179586, COSV100095266; called by muse, mutect2
- AMER1 | c.2818T>C p.W940R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV57667550; called by muse, mutect2, varscan2
- AMER3 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100366876; called by muse, mutect2
- AMPD1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs142123340; called by muse, mutect2, varscan2
- AMPH | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 150/287 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs368302578; called by muse, mutect2, varscan2
- ANAPC5 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55845263, COSV55845406; called by muse, mutect2, varscan2
- ANGPT2 | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 195/407 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV57337682; called by muse, mutect2, varscan2
- ANK1 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776721065, COSV55894829; called by muse, mutect2, varscan2
- ANK2 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52173519, COSV52186719; called by muse, mutect2, varscan2
- ANK3 | c.11933C>G p.T3978S | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV55060920, COSV99779017; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.7094C>A p.P2365H | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51857658; called by muse, mutect2, varscan2
- ANKMY1 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 98/103 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777963549, COSV56040470; called by muse, mutect2, varscan2
- ANKRD27 | c.2278A>G p.I760V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60135740; called by muse, mutect2, varscan2
- ANKRD33 | c.752C>T p.T251I (on ENST00000340970 / NM_001304459.2; = p.Q443* on NM_182608.4) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs779906105, COSV56608320; called by muse, varscan2
- ANKRD42 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764888146, COSV52618213; called by muse, mutect2, varscan2
- ANKS6 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV62052071; called by muse, mutect2, varscan2
- ANXA1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs752285742, COSV57412673; called by muse, mutect2, varscan2
- ANXA6 | c.1835T>C p.M612T | Missense Mutation (SNP) | VAF 168/397 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753583716, COSV62908309; called by muse, mutect2, varscan2
- ANXA6 | c.1518G>A p.T506= | Splice Region (SNP) | VAF 42/84 reads (50%) | catalogued as rs377149334, COSV62907323; called by muse, mutect2, varscan2
- ANXA6 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756721960, COSV62907893, COSV62908325; called by muse, mutect2, varscan2
- AP3B2 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55613959; called by muse, mutect2, varscan2
- AP5Z1 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs759329689, COSV100804128, COSV62243638; called by muse, mutect2, varscan2
- APBA1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1012439301, COSV55236683; called by muse, mutect2, varscan2
- APBB3 | c.1400G>A p.R467Q (on ENST00000357560 / NM_133173.2; = p.R474Q on NM_006051.3) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs773944900, COSV60366370; called by muse, mutect2, varscan2
- APC | c.326A>C p.E109A | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99970119; called by muse, mutect2
- APEX2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs147390902, COSV58193138; called by muse, mutect2, varscan2
- APOB | c.7477A>G p.I2493V | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1446693324, COSV99267852; called by muse, mutect2
- APOBR | c.1589C>T p.A530V (on ENST00000431282; = p.A539V on NM_018690.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.344); catalogued as rs777439097, COSV60493752; called by muse, mutect2, varscan2
- ARAP1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1393767675, COSV61994758; called by muse, mutect2, varscan2
- ARAP3 | c.3907C>A p.L1303I | Missense Mutation (SNP) | VAF 92/351 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV53354648; called by muse, mutect2, varscan2
- ARFGEF2 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100904463; called by muse, mutect2
- ARFGEF3 | c.5408C>G p.A1803G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV99292896; called by muse, mutect2
- ARHGAP1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs754102804, COSV61736027; called by muse, mutect2, varscan2
- ARHGAP20 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV52818742; called by muse, mutect2, varscan2
- ARHGDIG | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54733606; called by muse, mutect2, varscan2
- ARHGEF10 | c.3790G>A p.A1264T (on ENST00000398564; = p.A1239T on NM_014629.4) | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs373928792, COSV50675144; called by muse, mutect2, varscan2
- ARHGEF18 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs765089128, COSV60473748; called by muse, mutect2, varscan2
- ARHGEF26 | c.1538A>T p.D513V | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62851671; called by muse, mutect2, varscan2
- ARHGEF37 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs369500713; called by muse, mutect2, varscan2
- ARHGEF9 | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 238/571 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53644095; called by muse, mutect2, varscan2
- ARID1A | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 226/503 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs781266953, COSV61387934, COSV61388339; called by muse, mutect2, varscan2
- ARID1A | c.5385G>C p.K1795N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs200221564, COSV61388346; called by muse, mutect2, varscan2
- ARID2 | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as rs757890582, COSV57600222; called by muse, mutect2, varscan2
- ARID4B | c.3666G>A p.S1222= | Splice Region (SNP) | VAF 80/177 reads (45%) | catalogued as rs745757772, COSV99936273; called by muse, mutect2, varscan2
- ARID5A | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs374390790; called by muse, mutect2
- ARL6IP5 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774792987, COSV56235683, COSV99833029; called by muse, mutect2, varscan2
- ARMCX2 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782086194, COSV100168087, COSV57531153; called by muse, mutect2, varscan2
- ARPIN | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs376451415; called by muse, mutect2, varscan2
- ASAP2 | c.2438A>G p.D813G | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55638123; called by muse, mutect2, varscan2
- ASCL4 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV60816762; called by muse, mutect2, varscan2
- ASTE1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as rs1195834117, COSV53907814; called by muse, mutect2, varscan2
- ASTN1 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62491803, COSV62494609; called by muse, mutect2, varscan2
- ASTN1 | c.2134T>C p.C712R | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56083554; called by muse, mutect2, varscan2
- ATAD3B | c.*296G>A | Splice Region (SNP) | VAF 51/89 reads (57%) | catalogued as rs1281098355, COSV100426434, COSV58023194; called by muse, mutect2, varscan2
- ATF6 | c.1658A>G p.Q553R | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV63409979; called by muse, mutect2, varscan2
- ATF7IP | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53774760, COSV53777006; called by muse, mutect2, varscan2
- ATL1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 29/240 reads (12%) | catalogued as rs1442289748, COSV100613099, COSV63296580; called by muse, mutect2, varscan2
- ATP10A | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758536427, COSV63523642; called by muse, mutect2, varscan2
- ATP13A3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 93/198 reads (47%) | catalogued as rs777136013, COSV55467648, COSV55469323; called by muse, mutect2, varscan2
- ATP1A4 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs757712281, COSV63628397; called by muse, mutect2, varscan2
- ATP2A1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs149506518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs866709848, COSV62870848; called by muse, mutect2, varscan2
- ATP2C2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.46); catalogued as COSV52300966; called by muse, mutect2, varscan2
- ATP6V0A1 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 22/155 reads (14%) | catalogued as COSV52877686; called by muse, mutect2, varscan2
- ATP9A | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs888178293, COSV58766936; called by muse, mutect2, varscan2
- ATPAF1 | c.325C>T p.P109S (on ENST00000574428; = p.P132S on NM_022745.4) | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV61305721; called by muse, mutect2, varscan2
- ATRNL1 | c.3702del p.F1234Lfs*51 | Frame Shift Del (DEL) | VAF 113/281 reads (40%) | catalogued as rs782019775, COSV58101402; called by mutect2, pindel, varscan2
- ATRX | c.1841G>A p.G614D | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV64882903; called by muse, mutect2, varscan2
- AURKC | c.140G>A p.R47H (on ENST00000302804 / NM_001015878.2; = p.R13H on NM_003160.3) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs137858773; called by muse, mutect2, varscan2
- B3GNT3 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs756015682, COSV57952675; called by muse, mutect2, varscan2
- BAHCC1 | c.4571C>T p.A1524V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs782636842, COSV57032845; called by muse, mutect2, varscan2
- BAIAP3 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs760205376, COSV50103879, COSV99136177; called by muse, mutect2, varscan2
- BANK1 | c.2325G>T p.K775N | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59849354; called by muse, mutect2, varscan2
- BARHL2 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs765834036, COSV64981986; called by muse, mutect2, varscan2
- BAZ2B | c.5882A>G p.H1961R | Missense Mutation (SNP) | VAF 116/129 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs1405461125, COSV58601792; called by muse, mutect2, varscan2
- BBS2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as rs374487957, COSV55328491; called by muse, mutect2, varscan2
- BBS7 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs369866009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL6 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51655549; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs754078059; called by mutect2, pindel, varscan2
- BCLAF1 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as rs866470210, COSV50360614; called by muse, mutect2, varscan2
- BCOR | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); catalogued as rs372187961, COSV100652995, COSV60711390; called by muse, mutect2, varscan2
- BEST3 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs568860338, COSV58305341; called by muse, mutect2, varscan2
- BFSP2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100183843, COSV56591758; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 42/187 reads (22%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNIP5 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.179); catalogued as rs576970172, COSV71325557; called by muse, mutect2, varscan2
- BOP1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs908179759, COSV56639104; called by muse, mutect2, varscan2
- BPIFA3 | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64926224; called by muse, mutect2, varscan2
- BRD4 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs774596084, COSV54594527; called by muse, mutect2, varscan2
- BRWD3 | c.3719G>A p.R1240Q | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV64752276, COSV64753268; called by muse, mutect2, varscan2
- BSDC1 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756871320, COSV61983324; called by muse, mutect2, varscan2
- BTG4 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV63636882; called by muse, mutect2, varscan2
- C19orf47 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV63510977; called by muse, mutect2, varscan2
- C1QTNF4 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.146); catalogued as rs770883403; called by muse, varscan2
- C1QTNF6 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs775910598, COSV55395625; called by muse, mutect2, varscan2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 28/80 reads (35%) | catalogued as rs780657010; called by mutect2, varscan2
- C1orf116 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 240/512 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV63944676; called by muse, mutect2, varscan2
- C1orf198 | c.928-2A>G p.X310_splice | Splice Site (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100793502; called by muse, mutect2
- C1orf53 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs372599540; called by muse, mutect2, varscan2
- C2CD2L | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776891538, COSV60884749; called by muse, mutect2, varscan2
- C3 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as rs765367888, COSV55580890; called by muse, mutect2, varscan2
- C3orf20 | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.295); catalogued as rs931721224, COSV53789082; called by muse, mutect2, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, mutect2, varscan2
- C8A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777495880, COSV63483150; called by muse, mutect2, varscan2
- CACNA1B | c.5220G>A p.A1740= | Splice Region (SNP) | VAF 87/187 reads (47%) | catalogued as rs200577607, COSV53147180; called by muse, mutect2, varscan2
- CACNA1C | c.3235G>T p.G1079W | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59766943; called by muse, mutect2, varscan2
- CACNA1E | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 120/213 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); catalogued as rs774490890, COSV62417797; called by muse, mutect2, varscan2
- CAD | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.552); catalogued as rs925539009, COSV53031482; called by muse, mutect2, varscan2
- CALCOCO1 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1282288769, COSV50422434; called by muse, mutect2, varscan2
- CALCOCO1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs145201013; called by muse, mutect2, varscan2
- CAMKK1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs761162696, COSV50125412; called by muse, mutect2, varscan2
- CAMTA2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs200042464, COSV61788764; called by muse, mutect2, varscan2
- CANX | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1384938731, COSV99910660; called by muse, mutect2
- CAPN9 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774266028, COSV99681079; called by muse, mutect2
- CASP8 | c.1055C>A p.P352H (on ENST00000432109 / NM_033355.3; = p.P369H on NM_001228.4) | Missense Mutation (SNP) | VAF 83/88 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51855834; called by muse, mutect2, varscan2
- CATSPER1 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.188); catalogued as COSV56413257; called by muse, mutect2, varscan2
- CAVIN2 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as rs1485548061, COSV58425776; called by muse, mutect2, varscan2
- CBX7 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as rs753630073, COSV53358879; called by muse, mutect2, varscan2
- CCDC112 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as COSV101100522; called by muse, mutect2
- CCDC116 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs777433286, COSV53038690; called by muse, mutect2, varscan2
- CCDC116 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as rs774127975, COSV53038694; called by muse, mutect2, varscan2
- CCDC159 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs1207614963; called by muse, mutect2
- CCDC174 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs773126505, COSV99514525; called by muse, mutect2
- CCDC180 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs573049868, COSV63832050; called by muse, mutect2, varscan2
- CCDC27 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs148011284; called by muse, mutect2, varscan2
- CCDC27 | c.1915dup p.L639Pfs*? | Frame Shift Ins (INS) | VAF 28/66 reads (42%) | catalogued as rs751021664; called by mutect2, varscan2
- CCDC8 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.624); catalogued as rs746276818, COSV100281860, COSV56774945; called by muse, mutect2, varscan2
- CCKBR | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as rs1486107457, COSV58105190; called by muse, mutect2, varscan2
- CCND3 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs540997482, COSV57829581; called by muse, mutect2, varscan2
- CCNK | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 51/102 reads (50%) | catalogued as COSV66275767; called by muse, mutect2, varscan2
- CCSER1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774767718, COSV61465180; called by muse, mutect2, varscan2
- CD163L1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs148507764, COSV58014973; called by muse, mutect2, varscan2
- CD180 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1038384169, COSV56516797, COSV56517903; called by muse, mutect2, varscan2
- CD200R1L | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 160/348 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs369844409; called by muse, mutect2
- CD5 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776691755, COSV61718500; called by muse, mutect2, varscan2
- CDC27 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs74390782; called by muse, mutect2, varscan2
- CDC42BPA | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 98/195 reads (50%) | catalogued as rs758392312, COSV62019861; called by muse, mutect2, varscan2
- CDC42BPG | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs779954635, COSV100712151; called by muse, mutect2
- CDH17 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs751084277, COSV50327005; called by muse, mutect2, varscan2
- CDH23 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs559734973, COSV54938096; called by muse, mutect2, varscan2
- CDH23 | c.8851C>A p.L2951M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56487598; called by muse, mutect2, varscan2
- CDH23 | c.9151C>T p.Q3051* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV56487610; called by muse, mutect2, varscan2
- CDH4 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.047); catalogued as COSV64673295; called by muse, mutect2, varscan2
- CDH4 | c.2665G>C p.G889R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV64673299; called by muse, mutect2, varscan2
- CDIN1 | c.301C>T p.R101W (on ENST00000437989; = p.R3W on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201835784; called by muse, mutect2, varscan2
- CDK19 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1340287712, COSV60453259; called by muse, mutect2, varscan2
- CDRT1 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1245706744, COSV63054296; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 72/168 reads (43%) | catalogued as rs759091263; called by mutect2, varscan2
- CEACAM3 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 32/514 reads (6%) | catalogued as rs201591864, COSV99705108; called by muse, mutect2
- CEACAM5 | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55754853; called by muse, varscan2
- CELSR1 | c.5544dup p.T1849Dfs*23 | Frame Shift Ins (INS) | VAF 36/81 reads (44%) | catalogued as rs776824429; called by mutect2, varscan2
- CELSR2 | c.7648C>T p.R2550W | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs375989725; called by muse, mutect2, varscan2
- CEMIP2 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs537759272, COSV65485495; called by muse, mutect2, varscan2
- CENPX | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60712879; called by muse, mutect2, varscan2
- CEP350 | c.4076A>G p.Q1359R | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV62601982, COSV62609322; called by muse, mutect2, varscan2
- CEP89 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs182600896, COSV59867510; called by muse, mutect2, varscan2
- CES4A | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as COSV58652379, COSV58658128; called by muse, mutect2, varscan2
- CFAP61 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1366161478, COSV55646183; called by muse, mutect2, varscan2
- CFAP92 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 132/282 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs375148155; called by muse, mutect2, varscan2
- CHCHD3 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99366834; called by muse, mutect2
- CHMP5 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV56303826; called by muse, mutect2, varscan2
- CHP2 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573488303, COSV55650157; called by muse, mutect2, varscan2
- CHPF2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs199526960, COSV50389269; called by muse, mutect2, varscan2
- CHRM1 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs768728353, COSV61007605; called by muse, mutect2, varscan2
- CHRM4 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs1248863002, COSV63127420; called by muse, mutect2, varscan2
- CHRNA10 | c.1136del p.P379Qfs*21 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs748764774; called by mutect2, pindel, varscan2
- CHRND | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147919651, COSV51330303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHSY1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs569937094, COSV54255841; called by muse, mutect2, varscan2
- CIC | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs376580917; called by muse, mutect2, varscan2
- CIDEA | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV57600599; called by muse, mutect2, varscan2
- CIT | c.5807G>A p.R1936H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs1439854942, COSV55882232; called by muse, mutect2, varscan2
- CKAP2L | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 184/402 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs535556276, COSV56698151; called by muse, mutect2, varscan2
- CLASRP | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.21); catalogued as rs368668967; called by muse, mutect2, varscan2
- CLASRP | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.1); catalogued as rs969857750, COSV55519073; called by muse, varscan2
- CLCN2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs145746859; called by muse, mutect2, varscan2
- CLEC16A | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as COSV68501831; called by muse, mutect2, varscan2
- CLIC4 | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV65527603; called by muse, mutect2, varscan2
- CLTC | c.3881G>T p.G1294V | Missense Mutation (SNP) | VAF 105/208 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252866; called by muse, mutect2, varscan2
- CLTCL1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 94/188 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54238645; called by muse, mutect2, varscan2
- CMIP | c.1222C>T p.R408C (on ENST00000537098 / NM_198390.2; = p.R314C on NM_030629.3) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs781052399, COSV67700235; called by muse, mutect2, varscan2
- CMYA5 | c.2938T>A p.S980T | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV71409295; called by muse, mutect2, varscan2
- CNGB1 | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756012260, COSV51906651; called by muse, mutect2, varscan2
- CNTN6 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | catalogued as rs1377470355, COSV63165024, COSV63188401; called by muse, mutect2, varscan2
- CNTRL | c.4462G>A p.A1488T | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV53053121; called by muse, mutect2, varscan2
- COG4 | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206169304, COSV55367443; called by muse, mutect2, varscan2
- COG4 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 197/409 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV60425053; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 51/121 reads (42%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL16A1 | c.3166C>A p.P1056T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54713244; called by muse, mutect2, varscan2
- COL17A1 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs533717233, COSV62227880; called by muse, varscan2
- COL17A1 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as rs747301994, CM160838, COSV62229246; called by muse, varscan2
- COL1A1 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs72648344, CM070684, COSV56809190; called by muse, mutect2, varscan2
- COL1A2 | c.81+2T>C p.X27_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | catalogued as COSV51965581, COSV99800755; called by muse, mutect2, varscan2
- COL1A2 | c.3772C>T p.R1258C | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766273613, COSV51965590; called by muse, mutect2, varscan2
- COL20A1 | c.3022G>A p.V1008I | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs540834802, COSV58912703; called by muse, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 26/62 reads (42%) | catalogued as rs760493024; called by mutect2, varscan2
- COL27A1 | c.3811G>A p.V1271I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs558210767, COSV61922131; called by muse, mutect2, varscan2
- COL27A1 | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201559884, COSV61926880; called by muse, mutect2, varscan2
- COL28A1 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV68084422; called by muse, mutect2, varscan2
- COL4A2 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531542947, COSV64624330; called by muse, mutect2
- COL4A4 | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 87/94 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372606845, CM148122, COSV61630020; called by muse, mutect2, varscan2
- COL6A2 | c.1180-2A>G p.X394_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV56015484; called by muse, mutect2, varscan2
- COL6A6 | c.5707G>A p.V1903M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV62036405; called by muse, mutect2, varscan2
- COMMD10 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV57240620; called by muse, mutect2, varscan2
- CPB2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186705993, COSV51677269; called by muse, mutect2, varscan2
- CPNE1 | c.1507G>A p.A503T (on ENST00000352393; = p.A508T on NM_003915.5) | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs774263481, COSV58294767; called by muse, mutect2, varscan2
- CPT1A | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as rs112620511; called by muse, mutect2, varscan2
- CRAMP1 | c.3167C>T p.P1056L | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs757328704, COSV51965801; called by muse, mutect2, varscan2
- CRB2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs571013901, COSV63502278; called by muse, mutect2, varscan2
- CREBBP | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52139687; called by muse, mutect2, varscan2
- CRYZ | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV61718561; called by muse, mutect2, varscan2
- CSF1R | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs767113303, COSV53842527, COSV99641259; called by muse, mutect2, varscan2
- CSMD1 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 59/119 reads (50%) | catalogued as COSV68254893; called by muse, mutect2, varscan2
- CSMD1 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68254899; called by muse, mutect2, varscan2
- CTCFL | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429635968, COSV54778791; called by muse, mutect2, varscan2
- CTNND1 | c.2815G>A p.E939K (on ENST00000399050 / NM_001085458.2; = p.E912K on NM_001331.3) | Missense Mutation (SNP) | VAF 91/185 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as rs763409650, COSV62386053; called by muse, mutect2, varscan2
- CTNS | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757009591, COSV99251539; called by muse, mutect2, varscan2
- CTRL | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs147636333; called by muse, mutect2, varscan2
- CXADR | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.1); catalogued as COSV53031199; called by muse, mutect2, varscan2
- CYP2A6 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747024492, COSV56537063; called by muse, mutect2, varscan2
- CYP2S1 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs759878389, COSV100027369, COSV59506212; called by muse, mutect2, varscan2
- CYP4B1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV54726037; called by muse, mutect2, varscan2
- CYP4F11 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56125604, COSV56129330; called by muse, mutect2, varscan2
- DAAM2 | c.2963G>A p.R988Q (on ENST00000274867 / NM_001201427.2; = p.R987Q on NM_015345.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs750047168, COSV51336289, COSV51419475; called by muse, mutect2, varscan2
- DAGLA | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.972); catalogued as COSV57199439; called by muse, mutect2, varscan2
- DAXX | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV56472463; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 18/31 reads (58%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBP | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55341962, COSV99709701; called by muse, mutect2, varscan2
- DBX1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV57055206; called by muse, mutect2, varscan2
- DBX2 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.163); catalogued as rs769979631, COSV60339653; called by muse, mutect2, varscan2
- DCAF5 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58462942; called by muse, mutect2, varscan2
- DCC | c.3674C>A p.A1225D | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71440162; called by muse, mutect2, varscan2
- DCHS1 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs761187405, COSV55036733; called by muse, mutect2, varscan2
- DCLK2 | c.1510A>G p.R504G | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV56211603; called by muse, mutect2, varscan2
- DCLK3 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004014654, COSV69364469, COSV69364651; called by muse, mutect2, varscan2
- DCTN1 | c.3712C>G p.Q1238E | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778307537, COSV62621448; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DCTN4 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.379); catalogued as rs138887048; called by muse, mutect2, varscan2
- DDIAS | c.393G>A p.T131= | Splice Region (SNP) | VAF 71/164 reads (43%) | catalogued as rs762266588, COSV61273188; called by muse, mutect2, varscan2
- DDX46 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs773638519, COSV100844942, COSV62800936; called by muse, mutect2, varscan2
- DDX49 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs755888557, COSV55358732; called by muse, mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs757771764; called by mutect2, varscan2
- DDX60L | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99488396; called by muse, mutect2
- DENND4B | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1429028016, COSV63411754; called by muse, mutect2, varscan2
- DENND4B | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs770425187, COSV57845501; called by muse, mutect2, varscan2
- DERL3 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51956015; called by muse, mutect2, varscan2
- DGCR2 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs140698397; called by muse, mutect2, varscan2
- DGKB | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs745444233, COSV51790666, COSV51816432; called by muse, mutect2, varscan2
- DGKZ | c.2662G>A p.D888N (on ENST00000454345 / NM_001105540.2; = p.D700N on NM_003646.4) | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs757806104, COSV58994661; called by muse, mutect2, varscan2
- DHCR24 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 56/102 reads (55%) | catalogued as rs563822834, COSV64875432; called by muse, mutect2, varscan2
- DHRS13 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149335962; called by muse, mutect2, varscan2
- DHTKD1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as rs755528865, COSV53803758; called by muse, mutect2, varscan2
- DHX33 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs573048573, COSV56580744; called by muse, mutect2, varscan2
- DHX34 | c.2951G>A p.S984N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as COSV60895449, COSV60898012; called by muse, mutect2, varscan2
- DHX58 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1555661603, COSV52428093; called by muse, mutect2, varscan2
- DHX9 | c.709T>A p.L237M | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.893); catalogued as COSV62362083; called by muse, mutect2, varscan2
- DIDO1 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs533029215, COSV56633370; called by muse, mutect2, varscan2
- DIPK1C | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV59726433; called by muse, mutect2, varscan2
- DIS3L2 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs774732040, COSV56062854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP1 | c.538del p.S180Vfs*5 | Frame Shift Del (DEL) | VAF 79/211 reads (37%) | catalogued as COSV52657847; called by mutect2, pindel, varscan2
- DISP1 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs545584717, COSV52661595; called by muse, mutect2, varscan2
- DLG4 | c.2012G>A p.R671H (on ENST00000399506 / NM_001321075.3; = p.R714H on NM_001365.4) | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.294); catalogued as rs765807698, COSV57241908; called by muse, mutect2, varscan2
- DMXL1 | c.3262G>T p.G1088C | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60720288; called by muse, mutect2, varscan2
- DNAAF1 | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); catalogued as rs374905502, COSV58989161; called by muse, mutect2, varscan2
- DNAH1 | c.9407C>T p.T3136M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs567406387, COSV70233452; called by muse, mutect2, varscan2
- DNAH17 | c.12390dup p.N4131Qfs*13 | Frame Shift Ins (INS) | VAF 22/45 reads (49%) | catalogued as rs757601640; called by mutect2, varscan2
- DNAH17 | c.2287G>T p.G763C | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67760693; called by muse, mutect2, varscan2
- DNAH2 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377310831, COSV50022738; called by muse, mutect2, varscan2
- DNAH5 | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV54249968; called by muse, mutect2, varscan2
- DNAH7 | c.7325G>A p.R2442H | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs367603249; called by muse, mutect2, varscan2
- DNAH9 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs748910163, COSV52375155; called by muse, mutect2, varscan2
- DNAH9 | c.7768G>A p.V2590I | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs1202617030, COSV52375161; called by muse, mutect2, varscan2
- DNAI4 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.42); catalogued as rs1189456031, COSV63085793; called by muse, mutect2, varscan2
- DNAJC11 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 55/124 reads (44%) | catalogued as COSV53790673; called by muse, mutect2, varscan2
- DNHD1 | c.11425C>T p.R3809C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1428201931, COSV54443073; called by muse, mutect2, varscan2
- DNMBP | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV60632580; called by muse, mutect2, varscan2
- DOCK1 | c.5422G>A p.V1808M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs779069875, COSV54736133; called by muse, mutect2, varscan2
- DPY19L1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60584155; called by muse, mutect2, varscan2
- DPY19L1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747280371, COSV60584161; called by muse, mutect2, varscan2
- DSG4 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57397234; called by muse, mutect2, varscan2
- DSP | c.7915C>T p.R2639W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771553674, COSV65791818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTL | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs557642530, COSV65343136; called by muse, mutect2, varscan2
- DTX2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs747982040, COSV56858623, COSV56863250; called by muse, mutect2, varscan2
- DUS1L | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV60785469; called by muse, mutect2, varscan2
- DUSP23 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs756864682, COSV63660466; called by muse, mutect2, varscan2
- DYNC1H1 | c.12526C>T p.R4176C | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64142003; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs1409099723, COSV55776265; called by mutect2, varscan2
- EBF1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58193946; called by muse, mutect2, varscan2
- EDRF1 | c.3682G>A p.A1228T (on ENST00000356792 / NM_001202438.2; = p.A1194T on NM_015608.2) | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs202125749, COSV61766221; called by muse, mutect2, varscan2
- EFCAB6 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs200231368; called by muse, varscan2
- EGR1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as COSV53518056; called by muse, mutect2, varscan2
- EHBP1L1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759333764, COSV57079875; called by muse, mutect2, varscan2
- EIF3M | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV60073532; called by muse, mutect2, varscan2
- EIF4G3 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV51682673; called by muse, mutect2, varscan2
- EIPR1 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66132965; called by muse, mutect2, varscan2
- ELL2 | c.1416G>T p.K472N | Missense Mutation (SNP) | VAF 129/275 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1247462732, COSV52985047, COSV99427473; called by muse, mutect2, varscan2
- ELMO3 | c.2215C>T p.R739C (on ENST00000652269; = p.R686C on NM_024712.5) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs572713732, COSV58527443; called by muse, mutect2, varscan2
- EMCN | c.496T>G p.S166A | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.374); catalogued as COSV56457751; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- EML3 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs1165597557, COSV53874634; called by muse, mutect2, varscan2
- ENOX1 | c.1160A>G p.Q387R | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV54917229; called by muse, mutect2, varscan2
- EPB42 | c.1571C>T p.A524V (on ENST00000441366 / NM_001114134.2; = p.A554V on NM_000119.3) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV55751488; called by muse, mutect2, varscan2
- EPHA10 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs562741164, COSV57626370; called by muse, mutect2, varscan2
- EPM2AIP1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs776280016, COSV99212684; called by muse, mutect2
- EPN1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1185477423, COSV50043793; called by muse, mutect2, varscan2
- EPS15 | c.2330C>A p.T777N | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV65545183; called by muse, mutect2, varscan2
- EPSTI1 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV58048776; called by muse, mutect2, varscan2
- EPX | c.1591C>A p.R531S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.777); catalogued as COSV56598381, COSV56599069; called by muse, mutect2, varscan2
- ERBB2 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1196082930, COSV54076272; called by muse, mutect2, varscan2
- ERC1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 110/213 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142350281; called by muse, mutect2, varscan2
- ERF | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.087); catalogued as rs745819984, COSV55897355; called by muse, mutect2, varscan2
- ERG | c.926G>A p.R309H (on ENST00000398919 / NM_001243428.1; = p.R285H on NM_004449.4) | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs774038422, COSV55736507; called by muse, mutect2, varscan2
- ERLEC1 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV51753500; called by muse, varscan2
- ERN1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761547515, COSV70502088; called by muse, mutect2, varscan2
- ERN1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1248269311, COSV70504594; called by muse, mutect2, varscan2
- ESPL1 | c.1368C>T p.T456= | Splice Region (SNP) | VAF 56/116 reads (48%) | catalogued as rs756038295, COSV57762251; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 96/118 reads (81%) | catalogued as rs775950025; called by mutect2, varscan2
- ESS2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768922267, COSV52817239; called by muse, mutect2, varscan2
- ESS2 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52818746; called by muse, mutect2, varscan2
- ESX1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV65425096; called by muse, mutect2, varscan2
- ESYT1 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs141902607; called by muse, mutect2, varscan2
- EXOSC10 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as rs770343987, COSV58667944; called by muse, mutect2, varscan2
- EXOSC10 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs757576637, COSV58667960; called by muse, mutect2, varscan2
- EXTL1 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746131146, COSV65333313; called by muse, mutect2, varscan2
- EZHIP | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV57957573, COSV57957698; called by muse, mutect2, varscan2
- F10 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV65023061; called by muse, mutect2, varscan2
- F8 | c.4906C>T p.Q1636* | Nonsense Mutation (SNP) | VAF 138/293 reads (47%) | catalogued as CM055171, COSV64278315; called by muse, mutect2, varscan2
- FAM107A | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755089230, COSV62981285; called by muse, mutect2, varscan2
- FAM114A1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs891250063, COSV62674948; called by muse, mutect2
- FAM166C | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56603486; called by muse, mutect2, varscan2
- FAM199X | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as rs781953803, COSV55433088; called by muse, mutect2, varscan2
- FAM47B | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs200918267, COSV61452687, COSV61453630; called by muse, mutect2, varscan2
- FANCA | c.3610C>T p.R1204W | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs759303096, COSV57072969; called by muse, mutect2, varscan2
- FARP2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 105/116 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs375677515; called by muse, mutect2, varscan2
- FASTKD5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760731320, COSV53905290; called by muse, mutect2, varscan2
- FAT1 | c.13409C>T p.A4470V | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV71675864; called by muse, mutect2, varscan2
- FBF1 | c.2347C>T p.L783= (on ENST00000586717; = p.L797= on NM_001319193.1) | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as rs1455566534, COSV100045579; called by muse, varscan2
- FBLN7 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667498; called by muse, mutect2, varscan2
- FBN2 | c.1973A>G p.D658G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52543623; called by muse, mutect2, varscan2
- FBXL7 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1275721257, COSV61648197; called by muse, mutect2, varscan2
- FBXO17 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs549735835, COSV53070190, COSV53071564; called by muse, mutect2, varscan2
- FBXO34 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV58256894; called by muse, mutect2, varscan2
- FCGBP | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1033409632; called by muse, mutect2, varscan2
- FER1L5 | c.4448G>A p.R1483H (on ENST00000623019; = p.R1456H on NM_001293083.2) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67606992; called by muse, mutect2, varscan2
- FGD1 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1378980848, COSV64309595; called by muse, mutect2, varscan2
- FHOD3 | c.1882T>C p.S628P (on ENST00000359247 / NM_001281739.3; = p.S645P on NM_025135.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV57187798; called by muse, mutect2, varscan2
- FIG4 | c.2222C>T p.T741M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1274229885, COSV57791213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 79/207 reads (38%) | catalogued as rs1216734611; called by mutect2, pindel, varscan2
- FKBP4 | c.672-2A>G p.X224_splice | Splice Site (SNP) | VAF 117/272 reads (43%) | catalogued as rs755320293, COSV50008864; called by muse, mutect2, varscan2
- FLG | c.5207C>T p.A1736V | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV64248389; called by muse, varscan2
- FLG | c.5194C>T p.Q1732* | Nonsense Mutation (SNP) | VAF 120/248 reads (48%) | catalogued as COSV64248392; called by muse, varscan2
- FLNA | c.6007C>T p.R2003C (on ENST00000369850 / NM_001110556.2; = p.R1995C on NM_001456.3) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV61050925; called by muse, mutect2, varscan2
- FLNA | c.2482C>T p.R828C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1557178272, COSV61042467; called by muse, mutect2, varscan2
- FLNA | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV61045803; called by muse, mutect2, varscan2
- FLRT2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160468989, COSV58145329; called by muse, mutect2, varscan2
- FLT3 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs145998293, COSV54052899; ClinVar: not provided; called by muse, mutect2, varscan2
- FMOD | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1325044595, COSV61609652, COSV61610029; called by muse, mutect2, varscan2
- FNDC1 | c.4484C>T p.T1495M | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs564106720, COSV51947396; called by muse, mutect2, varscan2
- FNDC7 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765229312, COSV54757640; called by muse, mutect2, varscan2
- FOXJ3 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780372538, COSV62363240; called by muse, mutect2, varscan2
- FOXO1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65425906; called by muse, mutect2, varscan2
- FPR2 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.361); catalogued as rs1284273058, COSV100389441; called by muse, mutect2, varscan2
- FRA10AC1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs769873184, COSV63273722; called by muse, mutect2, varscan2
- FRMD1 | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV51964769; called by muse, mutect2, varscan2
- FRMD5 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 134/260 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781351864, COSV68725189; called by muse, mutect2, varscan2
- FRYL | c.573G>A p.K191= | Splice Region (SNP) | VAF 10/203 reads (5%) | catalogued as COSV99978010; called by muse, mutect2
- FSD1 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.786); catalogued as COSV55698716; called by muse, mutect2, varscan2
- FSD2 | c.489C>G p.C163W | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs752167870, COSV58012591; called by muse, mutect2, varscan2
- FSTL5 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1177305826, COSV60227098; called by muse, mutect2, varscan2
- FUBP3 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753338109, COSV60514646; called by muse, mutect2, varscan2
- FZD10 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs770701893, COSV57472020; called by muse, mutect2, varscan2
- FZD2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59530155; called by muse, mutect2, varscan2
- FZD4 | c.1312G>T p.G438W | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72294696; called by muse, mutect2, varscan2
- GABRA4 | c.4G>A p.V2I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.352); catalogued as rs760495497, COSV51934787; called by muse, mutect2, varscan2
- GALC | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 18/404 reads (4%) | catalogued as COSV99730474; called by muse, mutect2
- GALNT11 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759847312, COSV57427082; called by muse, mutect2, varscan2
- GALNT14 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 278/605 reads (46%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.49); catalogued as rs955498267, COSV61110731; called by muse, mutect2, varscan2
- GANAB | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs142226736; called by muse, mutect2, varscan2
- GAREM1 | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV52515598; called by muse, mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GDPD5 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61130120; called by muse, mutect2, varscan2
- GEMIN5 | c.2660T>A p.V887D | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.046); catalogued as COSV53564546; called by muse, mutect2, varscan2
- GIMAP1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.58); catalogued as COSV100212326, COSV56189766; called by muse, mutect2
- GIN1 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 93/163 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV67537740; called by muse, mutect2, varscan2
- GIT2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs896776603, COSV58080742; called by muse, mutect2, varscan2
- GJA8 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs782044825, COSV53787808; called by muse, mutect2, varscan2
- GLB1L3 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760168504, COSV66283231; called by muse, mutect2, varscan2
- GLG1 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52669610; called by muse, mutect2
- GMEB2 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV56609538; called by muse, varscan2
- GNA12 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs200756903, COSV51740164; called by muse, mutect2, varscan2
- GNAZ | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV50741454; called by muse, mutect2, varscan2
- GNE | c.1864G>A p.A622T (on ENST00000396594 / NM_001128227.3; = p.A591T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as rs752286512, CM067674, COSV64951273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNG7 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs773705229, COSV66288020; called by muse, mutect2, varscan2
- GNLY | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs773452688, COSV55704569; called by muse, mutect2, varscan2
- GNPTAB | c.2093T>C p.V698A | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV68449963; called by muse, mutect2, varscan2
- GOLGA3 | c.4297C>T p.Q1433* | Nonsense Mutation (SNP) | VAF 35/66 reads (53%) | catalogued as COSV52642435; called by muse, mutect2, varscan2
- GOLGA3 | c.3583-2A>G p.X1195_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52642443; called by muse, mutect2, varscan2
- GOLGA7 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1362179420, COSV63299734; called by muse, mutect2, varscan2
- GOLGB1 | c.9538C>T p.R3180W | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530077580, COSV61470615; called by muse, mutect2, varscan2
- GOLM2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as rs200685854, COSV55466244; called by muse, mutect2, varscan2
- GPATCH2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375962510; called by muse, mutect2, varscan2
- GPATCH3 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs776599206, COSV64652677; called by muse, mutect2, varscan2
- GPATCH8 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 77/81 reads (95%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs779466880, COSV59194954; called by muse, mutect2, varscan2
- GPI | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); catalogued as rs767621544, COSV62894476; called by muse, mutect2, varscan2
- GPR137 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs746357799, COSV57403849; called by muse, mutect2, varscan2
- GPR3 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs116605856, COSV100927547; called by muse, mutect2, varscan2
- GPR4 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.644); catalogued as rs768730163, COSV59917460; called by muse, mutect2, varscan2
- GPRIN1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs774184931, COSV56144758; called by muse, mutect2, varscan2
- GPX6 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV62658966; called by muse, mutect2, varscan2
- GREB1 | c.4905G>T p.Q1635H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52195611, COSV99303655; called by muse, mutect2, varscan2
- GREM2 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58950816; called by muse, mutect2, varscan2
- GRIA2 | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 86/351 reads (25%) | catalogued as COSV52404827; called by muse, mutect2, varscan2
- GRID1 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as COSV60050944; called by muse, mutect2, varscan2
- GRIK3 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs754585903, COSV66135244; called by muse, mutect2, varscan2
- GRK2 | c.1120T>C p.W374R | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57953908; called by muse, mutect2, varscan2
- GRM3 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 76/147 reads (52%) | catalogued as COSV64479098; called by muse, mutect2, varscan2
- GRM5 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59627489; called by muse, mutect2, varscan2
- GTF3C1 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1205133504, COSV62244312; called by muse, mutect2, varscan2
- GTPBP6 | c.1537C>A p.L513I | Missense Mutation (SNP) | VAF 149/339 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58205640; called by muse, mutect2, varscan2
- GUCY1A1 | c.1861A>T p.T621S | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56656205; called by muse, mutect2, varscan2
- GUCY2D | c.2878G>A p.V960M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs781010216, COSV54696753; called by muse, mutect2, varscan2
- GUK1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs752446312, COSV57158150; called by muse, varscan2
- GYPE | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 185/386 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs763843605, COSV62261401; called by muse, mutect2, varscan2
- H2AC11 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as rs751969992, COSV60362716; called by muse, mutect2, varscan2
- H2BC1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 288/568 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.952); catalogued as COSV51236838, COSV51237665; called by muse, varscan2
- HAS3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs758922256, COSV54709119; called by muse, mutect2, varscan2
- HAVCR2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs372946929, COSV57154069; called by muse, mutect2, varscan2
- HCN1 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs371602396; called by muse, mutect2, varscan2
- HCRTR2 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV63796605; called by muse, mutect2, varscan2
- HDHD2 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs772089622, COSV56075555; called by muse, mutect2, varscan2
- HEBP2 | c.593del p.N198Mfs*26 | Frame Shift Del (DEL) | VAF 75/186 reads (40%) | catalogued as rs769528102, COSV100874953; called by mutect2, pindel, varscan2
- HECA | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760164332, COSV62768949; called by muse, mutect2, varscan2
- HELZ | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs771405149, COSV62380794; called by muse, mutect2, varscan2
- HELZ2 | c.4832G>A p.R1611H (on ENST00000467148 / NM_001037335.2; = p.R1042H on NM_033405.3) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs779686338, COSV71296971; called by muse, mutect2, varscan2
- HEMK1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192523417, COSV51751968; called by muse, mutect2, varscan2
- HERC5 | c.418del p.I140* | Frame Shift Del (DEL) | VAF 49/120 reads (41%) | catalogued as rs770854785; called by mutect2, varscan2
- HEY2 | c.549T>G p.H183Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV64240671; called by muse, mutect2, varscan2
- HFE | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 63/128 reads (49%) | catalogued as COSV58513471; called by muse, mutect2, varscan2
- HIPK2 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV61232342; called by muse, mutect2, varscan2
- HIRIP3 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV54230770; called by muse, mutect2, varscan2
- HIVEP1 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65104853; called by muse, mutect2, varscan2
- HIVEP3 | c.5932C>T p.R1978C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs533252687, COSV56023031; called by muse, mutect2, varscan2
- HIVEP3 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56023040; called by muse, mutect2, varscan2
- HLCS | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756409633, COSV60797991; called by muse, mutect2, varscan2
- HMCN1 | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV54938507; called by muse, mutect2, varscan2
- HMCN1 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54938518; called by muse, mutect2, varscan2
- HMCN1 | c.4037C>A p.T1346N | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV54938527, COSV99627164; called by muse, mutect2, varscan2
- HMOX1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs143057716; called by muse, mutect2, varscan2
- HNF4A | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as rs1463436840, COSV57388380; called by muse, mutect2, varscan2
- HNF4A | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs1427687409, CM1310939, COSV57388834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPM | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1397210961, COSV55316921; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54562565; called by muse, mutect2, varscan2
- HOXA1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56067650; called by muse, mutect2, varscan2
- HRH3 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV58050315; called by muse, mutect2, varscan2
- HS6ST2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371646517, COSV63717992; called by muse, mutect2, varscan2
- HSPG2 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758631172, COSV65976916; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPH1 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765918581, COSV60710697; called by muse, mutect2, varscan2
- HTR1D | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58449113; called by muse, mutect2, varscan2
- HTRA2 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs766432598, COSV51213427; called by muse, mutect2, varscan2
- HUWE1 | c.7801C>T p.R2601W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs782271618, COSV99474090; called by muse, mutect2
- HYAL2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs782395850, COSV51701673; called by muse, mutect2, varscan2
- ICE1 | c.4531C>T p.R1511* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV56831806; called by muse, mutect2, varscan2
- ICMT | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV59474519; called by muse, mutect2, varscan2
- IFNLR1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as rs772253018, COSV59526510; called by muse, mutect2, varscan2
- IGF1R | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs1356080771, COSV51276334; called by muse, mutect2, varscan2
- IGFBP2 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 66/76 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs370035123, COSV52081178; called by muse, mutect2, varscan2
- IGFL2 | c.349C>T p.R117C (on ENST00000377693 / NM_001135113.2; = p.R128C on NM_001002915.2) | Missense Mutation (SNP) | VAF 19/367 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs544005376, COSV100890703; called by muse, mutect2
- IGSF1 | c.3858G>A p.W1286* | Nonsense Mutation (SNP) | VAF 139/288 reads (48%) | catalogued as COSV63840143; called by muse, mutect2, varscan2
- IGSF22 | c.1946C>T p.T649M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs547091323, COSV60038423; called by muse, mutect2, varscan2
- IGSF8 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1186474444, COSV58759081; called by muse, mutect2, varscan2
- IGSF9 | c.1540G>A p.V514M (on ENST00000368094 / NM_001135050.2; = p.V498M on NM_020789.4) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV63642369; called by muse, mutect2, varscan2
- IGSF9 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185127478, COSV63642381; called by muse, mutect2, varscan2
- IKBKB | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV60599706; called by muse, mutect2, varscan2
- IKBKB | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60599715; called by muse, mutect2, varscan2
- IL17RC | c.959G>A p.R320Q (on ENST00000295981 / NM_153461.4; = p.R234Q on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as rs373618087, COSV55974913; called by muse, mutect2
- IL25 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59306920; called by muse, mutect2, varscan2
- INHBA | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV54221855; called by muse, mutect2, varscan2
- INHBE | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56989011; called by muse, mutect2, varscan2
- INSC | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1234273411, COSV65412989; called by muse, varscan2
- INSR | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762687424, COSV57172674; called by muse, mutect2, varscan2
- INSYN2A | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs1223263750, COSV54731810; called by muse, mutect2
- INTS11 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs376430379, COSV60090280; called by muse, varscan2
- INTS7 | c.2672A>G p.Q891R | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65345225; called by muse, mutect2, varscan2
- IQCH | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs760122918, COSV60059466; called by muse, mutect2, varscan2
- IQGAP3 | c.3565G>A p.A1189T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs571490438, COSV63254440; called by muse, mutect2, varscan2
- IQSEC1 | c.1499T>A p.L500H | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56228860; called by muse, mutect2, varscan2
- IREB2 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs200306100, COSV51920429; called by muse, mutect2, varscan2
- IRF9 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV60703083; called by muse, mutect2, varscan2
- IRS4 | c.942T>A p.C314* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV64535824; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs749725763, COSV59349826; called by muse, mutect2, varscan2
- ITGA1 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as rs199550572, COSV50896647; called by muse, mutect2, varscan2
- ITGAL | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs147749266; called by muse, mutect2, varscan2
- ITGB2 | c.1438C>T p.R480C (on ENST00000302347; = p.R456C on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs146014032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB5 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs200580858; called by muse, mutect2, varscan2
- ITIH2 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV64435111; called by muse, mutect2, varscan2
- ITPR3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs376628421; called by muse, mutect2, varscan2
- IVNS1ABP | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs774840040, COSV62251697; called by muse, varscan2
- JAK2 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs895187915, COSV67638292; called by muse, mutect2, varscan2
- KALRN | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53779270; called by muse, mutect2, varscan2
- KANK2 | c.1453C>T p.R485W (on ENST00000586659 / NM_001379562.1; = p.R493W on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as rs981952023, COSV100763377; called by muse, mutect2
- KANK4 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV62989186; called by muse, mutect2, varscan2
- KASH5 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs551444461, COSV101483493, COSV71358444; called by muse, mutect2, varscan2
- KASH5 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV71358446; called by muse, mutect2, varscan2
- KAT14 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs370149832; called by muse, mutect2, varscan2
- KAT6A | c.4651A>G p.S1551G | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55911622, COSV99705346; called by muse, mutect2, varscan2
- KAT7 | c.1278A>T p.K426N | Missense Mutation (SNP) | VAF 213/233 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52016828; called by muse, mutect2, varscan2
- KCMF1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV69054725; called by muse, mutect2, varscan2
- KCNA6 | c.1022T>A p.L341H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54977718; called by muse, mutect2, varscan2
- KCNA6 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1400476551, COSV54977723; called by muse, varscan2
- KCNAB3 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs111968052; called by muse, mutect2, varscan2
- KCND3 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1332646922, COSV56175522; called by muse, mutect2, varscan2
- KCNN2 | c.638G>A p.R213H (on ENST00000264773; = p.R425H on NM_021614.4) | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745525548, COSV53293426; called by muse, mutect2, varscan2
- KCNQ2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV60433822; called by muse, mutect2, varscan2
- KCNQ3 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1554622834, COSV66480979; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNQ4 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV61275555; called by muse, mutect2, varscan2
- KDM4B | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50258341; called by muse, mutect2, varscan2
- KDM5A | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772550693, COSV66990084; called by muse, mutect2, varscan2
- KDM5B | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52512534; called by muse, mutect2, varscan2
- KDM6A | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV100937864, COSV65045305; called by muse, mutect2, varscan2
- KEL | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs747437444, COSV62333999; called by muse, mutect2, varscan2
- KIAA0232 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.91); catalogued as COSV56929160; called by muse, mutect2, varscan2
- KIAA0232 | c.3314G>A p.R1105Q | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371014807; called by muse, mutect2, varscan2
- KIAA1217 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV64612655; called by muse, mutect2, varscan2
- KIAA1755 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV54080327; called by muse, mutect2, varscan2
- KIF12 | c.698G>A p.R233Q (on ENST00000640217; = p.R95Q on NM_138424.1) | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750693411, COSV65117215, COSV65117952; called by muse, mutect2, varscan2
- KIF19 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs749524661, COSV63430533; called by muse, mutect2, varscan2
- KIF1A | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs766807173, COSV57481950; called by muse, mutect2
- KIF1B | c.1052C>T p.A351V (on ENST00000377086 / NM_001365952.1; = p.A345V on NM_015074.3) | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773162220, COSV55815656; called by muse, mutect2, varscan2
- KIF20A | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs564669414, COSV67510565; called by muse, mutect2, varscan2
- KIF21A | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 169/346 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs992012618, COSV62766656; called by muse, mutect2, varscan2
- KIF26B | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1335465590, COSV63636976; called by muse, mutect2
- KIF5C | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV69170962; called by muse, mutect2, varscan2
- KIF5C | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 74/77 reads (96%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as rs765950375, COSV68480336; called by muse, mutect2, varscan2
- KIF9 | c.2033G>A p.R678H (on ENST00000265529 / NM_001377474.1; = p.R613H on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs780366842, COSV55518897; called by muse, mutect2, varscan2
- KLC2 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV57584182; called by muse, mutect2, varscan2
- KLF16 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1425769878, COSV51737231; called by muse, mutect2, varscan2
- KLHL22 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs772432702, COSV61022728; called by muse, mutect2, varscan2
- KLHL23 | c.1285G>T p.G429* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as COSV55869421; called by muse, mutect2, varscan2
- KLHL25 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs542141942, COSV61994719; called by muse, mutect2, varscan2
- KLHL32 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs766818945, COSV65111992; called by muse, mutect2, varscan2
- KPNA1 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs192240632, COSV60271489; called by muse, mutect2, varscan2
- KRCC1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs756589562, COSV61252185; called by muse, mutect2, varscan2
- KREMEN1 | c.1012G>A p.E338K (on ENST00000407188; = p.E340K on NM_032045.5) | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs141945870, COSV59914714; called by muse, mutect2, varscan2
- KRT23 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 190/376 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544856938, COSV52928917; called by muse, mutect2, varscan2
- KRT3 | c.1626C>G p.Y542* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV58817191; called by muse, mutect2, varscan2
- KRT6A | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV58103694; called by muse, mutect2, varscan2
- L1TD1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV63134262; called by muse, mutect2, varscan2
- L3MBTL1 | c.2180C>T p.T727M (on ENST00000418998 / NM_001377303.1; = p.T637M on NM_015478.7) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs371775266; called by muse, mutect2, varscan2
- L3MBTL2 | c.1318C>A p.L440M | Missense Mutation (SNP) | VAF 141/281 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53435585; called by muse, mutect2, varscan2
- LAD1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs750609613, COSV66213259; called by muse, mutect2, varscan2
- LAMA2 | c.2080A>G p.M694V | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV70354584; called by muse, mutect2, varscan2
- LAMA5 | c.5953G>A p.D1985N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs757724884, COSV53371596; called by muse, mutect2, varscan2
- LAMB3 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs760667887, COSV61919511; called by muse, mutect2, varscan2
- LAMC3 | c.3053C>T p.A1018V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1217018895, COSV63095130; called by muse, mutect2, varscan2
- LARP1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 46/99 reads (46%) | PolyPhen benign (0.005); catalogued as COSV60431017; called by muse, mutect2, varscan2
- LCTL | c.705+2T>C p.X235_splice | Splice Site (SNP) | VAF 29/53 reads (55%) | catalogued as COSV58423071; called by muse, mutect2, varscan2
- LDLRAD2 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs187938808, COSV60827683; called by muse, mutect2, varscan2
- LDLRAD3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs367729929; called by muse, mutect2, varscan2
- LEFTY1 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.233); catalogued as rs1279996968, COSV55284073; called by muse, mutect2, varscan2
- LGALS8 | c.698G>A p.R233H (on ENST00000341872; = p.R275H on NM_006499.4) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs369820574; called by muse, mutect2, varscan2
- LIAS | c.740G>A p.R247H (on ENST00000261434 / NM_001363700.2; = p.R350H on NM_006859.4) | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779790258, COSV54697179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LILRA2 | c.1390G>A p.G464R (on ENST00000391738 / NM_001130917.3; = p.G447R on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs754197619, COSV52196427; called by muse, mutect2, varscan2
- LIMK1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs782653004, COSV60284441; called by muse, mutect2, varscan2
- LINGO1 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs912928791, COSV62438468; called by muse, mutect2, varscan2
- LIPE | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs778648244, COSV54925284; called by muse, mutect2, varscan2
- LNX2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60338249; called by muse, mutect2, varscan2
- LRFN3 | c.565C>A p.H189N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55819029; called by muse, mutect2, varscan2
- LRP11 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV53335267; called by muse, mutect2, varscan2
- LRP11 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs150922217; called by muse, mutect2, varscan2
- LRP2 | c.7624C>T p.R2542C | Missense Mutation (SNP) | VAF 65/69 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55549686, COSV99786393; called by muse, mutect2, varscan2
- LRP3 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1461845373, COSV53510852; called by muse, mutect2, varscan2
- LRRC10 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as rs775363286, COSV64060429; called by muse, mutect2, varscan2
- LRRC32 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV52634177; called by muse, mutect2, varscan2
- LRRC37B | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV58954764; called by muse, mutect2, varscan2
- LRRC47 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs750609662, COSV65563711; called by muse, mutect2, varscan2
- LRRC4B | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65350315; called by muse, mutect2, varscan2
- LRRC66 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV58632660; called by muse, mutect2, varscan2
- LRRIQ1 | c.3266G>A p.S1089N | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV67837879; called by muse, mutect2, varscan2
- LRRIQ4 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.455); catalogued as COSV61620124; called by muse, mutect2, varscan2
- LRRK1 | c.5455A>G p.M1819V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs368591954; called by muse, mutect2, varscan2
- LRSAM1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs141326230; called by muse, mutect2, varscan2
- LRTM1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1190189316, COSV55578754; called by muse, mutect2, varscan2
- LSR | c.1269dup p.S424Qfs*10 (on ENST00000361790; = p.S405Qfs*10 on NM_015925.6) | Frame Shift Ins (INS) | VAF 18/34 reads (53%) | catalogued as rs771235856; called by mutect2, varscan2
- LTA4H | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 97/213 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs747019580, COSV57383071; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 59/136 reads (43%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- LUZP4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs936115318, COSV64218417; called by muse, mutect2, varscan2
- LY75 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 413/434 reads (95%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs115323272, COSV55106571; called by muse, mutect2, varscan2
- MAGEA12 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63295426; called by muse, varscan2
- MAGEA3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs150714849, COSV64756304; called by muse, mutect2, varscan2
- MAGEC3 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV53581791, COSV74217448; called by muse, mutect2, varscan2
- MAGIX | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV66256501; called by muse, mutect2, varscan2
- MAN1A2 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62981361; called by muse, mutect2, varscan2
- MAP2 | c.2050A>G p.S684G | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV52306812; called by muse, mutect2, varscan2
- MAP3K1 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68124965; called by muse, mutect2, varscan2
- MAP3K12 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs199708842, COSV57235875; called by muse, mutect2, varscan2
- MAP3K15 | c.3464C>T p.A1155V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201603186, COSV58826934; called by muse, mutect2, varscan2
- MAPK7 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55191787; called by muse, mutect2, varscan2
- MARCHF11 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60127957, COSV60134415; called by muse, mutect2, varscan2
- MARCHF5 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62770696; called by muse, mutect2, varscan2
- MARS1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs769265396, COSV56258531; called by muse, mutect2, varscan2
- MARVELD3 | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752977838, COSV51705845; called by muse, mutect2, varscan2
- MASP2 | c.1065C>A p.D355E | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV68896210, COSV68897466; called by muse, mutect2, varscan2
- MAST2 | c.3356G>A p.R1119Q | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.888); catalogued as rs201688488, COSV63618702; called by muse, mutect2, varscan2
- MCC | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 85/177 reads (48%) | catalogued as rs1157838544, COSV100203060, COSV56734677; called by muse, mutect2, varscan2
- MCM3 | c.1001G>A p.G334E (on ENST00000229854 / NM_001366374.2; = p.G324E on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57719326; called by muse, mutect2, varscan2
- MCM3AP | c.5278C>T p.R1760W | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs762013245, COSV52437518; called by muse, mutect2, varscan2
- MCM3AP | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779630101, COSV52445284; called by muse, mutect2, varscan2
- MCM3AP | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762882197, COSV52436883; called by muse, mutect2, varscan2
- MCM7 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.956); catalogued as rs752169854, COSV57998714; called by muse, mutect2, varscan2
- MCOLN2 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.985); catalogued as rs760278838, COSV52298428; called by muse, mutect2, varscan2
- MDN1 | c.10525C>A p.H3509N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65529713; called by mutect2, varscan2
- MED1 | c.1384C>A p.L462M | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.855); catalogued as COSV56128332; called by muse, mutect2, varscan2
- MED24 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 191/432 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62420699; called by muse, mutect2, varscan2
- MEF2D | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs371370250; called by muse, mutect2
- MEGF6 | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV53895492; called by muse, mutect2, varscan2
- MEGF8 | c.4249G>A p.V1417I (on ENST00000251268 / NM_001271938.2; = p.V1350I on NM_001410.3) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.299); catalogued as rs756485611, COSV52100150; called by muse, mutect2, varscan2
- MEGF8 | c.4250T>C p.V1417A (on ENST00000251268 / NM_001271938.2; = p.V1350A on NM_001410.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV99238879; called by muse, mutect2, varscan2
- MEIOB | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1369786705, COSV58055563; called by muse, mutect2, varscan2
- MESD | c.632dup p.K212Efs*19 | Frame Shift Ins (INS) | VAF 66/162 reads (41%) | catalogued as rs745891632; called by mutect2, varscan2
- MET | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59263718; called by muse, mutect2
- METTL15 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57719443; called by muse, mutect2, varscan2
- METTL17 | c.1265+10del | Splice Region (DEL) | VAF 17/74 reads (23%) | catalogued as rs771419748, COSV100068730; called by mutect2, pindel, varscan2
- MEX3C | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV68530582; called by muse, mutect2, varscan2
- MEX3D | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183543; called by muse, varscan2
- MGA | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV54948042; called by muse, mutect2, varscan2
- MGA | c.2671G>A p.V891I | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs773866602, COSV54962360; called by muse, mutect2, varscan2
- MGAM | c.3285A>C p.E1095D | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV72075765; called by muse, mutect2, varscan2
- MICAL3 | c.5365C>T p.R1789C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs1048838166, COSV71588866; called by muse, varscan2
- MID2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1448332945, COSV53311667; called by muse, mutect2, varscan2
- MIDN | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1351601882, COSV56296822; called by muse, mutect2, varscan2
- MMP9 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs746936147, COSV63434457; called by muse, mutect2, varscan2
- MPRIP | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs925239576, COSV57930232; called by muse, mutect2, varscan2
- MRPL16 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 143/320 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774234238, COSV55701052; called by muse, mutect2, varscan2
- MRPL38 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1413161895, COSV53934714; called by muse, mutect2, varscan2
- MRPL40 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs938660014, COSV54279140; called by muse, mutect2, varscan2
- MRPS14 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs149343934, COSV62880676; called by muse, mutect2, varscan2
- MRS2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.407); catalogued as COSV51235432; called by muse, mutect2, varscan2
- MSI2 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 160/315 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs772710603, COSV52356315; called by muse, mutect2, varscan2
- MSRB1 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs771856577, COSV51908291; called by muse, mutect2, varscan2
- MSS51 | c.1333T>C p.C445R | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV55020616; called by muse, mutect2, varscan2
- MTAP | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1418053156, COSV66478511; called by muse, mutect2, varscan2
- MTIF2 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 118/236 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759800202, COSV55053983; called by muse, mutect2, varscan2
- MTOR | c.7568C>T p.T2523M | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as rs1255967230, COSV63869565; called by muse, mutect2, varscan2
- MTOR | c.5897G>A p.R1966Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1316157865, COSV63877868; called by muse, mutect2, varscan2
- MTR | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs1432236758, COSV63965951; called by muse, mutect2
- MUC2 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.2); catalogued as rs370519187; called by muse, mutect2, varscan2
- MUC20 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 89/629 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100291481; called by muse, mutect2
- MUC4 | c.13765C>T p.R4589* (on ENST00000463781 / NM_018406.7; = p.R353* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs771701130, COSV57801324; called by muse, mutect2, varscan2
- MUC6 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs200035476, COSV70142936; called by muse, mutect2, varscan2
- MYH1 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 163/328 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs770557823, COSV56849501, COSV99875018; called by muse, mutect2, varscan2
- MYH11 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs918714049, COSV55568193, COSV55572470; called by muse, mutect2, varscan2
- MYH11 | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55568217; called by muse, mutect2, varscan2
- MYH4 | c.4294C>T p.L1432F | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs551169093, COSV55125668; called by muse, mutect2, varscan2
- MYH7 | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs727504355, CM1411014, COSV62515978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL9 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs201816112, COSV54072959; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO1A | c.3098A>G p.K1033R | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as rs1263862652, COSV55653801; called by muse, mutect2, varscan2
- MYO1H | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs747396794, COSV60445254; called by muse, mutect2, varscan2
- MYO7B | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270888100, COSV67348560; called by muse, mutect2, varscan2
- MYPN | c.3101T>A p.L1034* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV62738850; called by muse, mutect2, varscan2
- NAA35 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144270495; called by muse, mutect2, varscan2
- NADK | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58272230; called by muse, mutect2, varscan2
- NAIF1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs147281899, COSV66090835, COSV66091326; called by muse, mutect2, varscan2
- NAT10 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs149812318, COSV57665928; called by muse, mutect2, varscan2
- NATD1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs533505555, COSV101204718; called by muse, mutect2, varscan2
- NAV2 | c.6028C>T p.R2010W (on ENST00000396087 / NM_001244963.2; = p.R1951W on NM_145117.5) | Missense Mutation (SNP) | VAF 170/345 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as rs749987451, COSV60664928; called by muse, mutect2, varscan2
- NCKAP5 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 87/162 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58473153; called by muse, mutect2, varscan2
- NCOA6 | c.4901C>T p.A1634V | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs146019486; called by muse, mutect2, varscan2
- NDRG1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs144310406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECAB3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs201270866; called by muse, mutect2, varscan2
- NEDD1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.944); catalogued as rs748497881, COSV57146708, COSV99901221; called by muse, mutect2, varscan2
- NEFM | c.2410G>T p.G804W | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55334829; called by muse, varscan2
- NEIL3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs114671957; called by muse, mutect2, varscan2
- NEIL3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs751294884, COSV52813417; called by muse, mutect2, varscan2
- NEK5 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as rs377168646; called by muse, mutect2, varscan2
- NELFB | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs748610658, COSV58026398; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 54/155 reads (35%) | catalogued as rs759081520; called by pindel, varscan2
- NES | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63962814; called by muse, varscan2
- NEUROD6 | c.193A>G p.R65G | Missense Mutation (SNP) | VAF 30/838 reads (4%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.699); catalogued as COSV99774190; called by muse, mutect2
- NFASC | c.1373C>T p.P458L (on ENST00000339876 / NM_001378329.1; = p.P469L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417515837, COSV58379027; called by muse, mutect2, varscan2
- NFE2 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229311861, COSV56457241; called by muse, mutect2, varscan2
- NFIL3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52683016; called by muse, mutect2, varscan2
- NFKB1 | c.2452C>T p.Q818* (on ENST00000394820 / NM_001382627.1; = p.Q819* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as COSV56960734; called by muse, mutect2, varscan2
- NFKB1 | c.2739G>T p.Q913H (on ENST00000394820 / NM_001382627.1; = p.Q914H on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.121); catalogued as rs766773037, COSV99897836; called by muse, mutect2
- NFKB2 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.567); catalogued as COSV50059734; called by muse, mutect2, varscan2
- NFKBID | c.476C>T p.T159M (on ENST00000396901; = p.T311M on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1271918065, COSV61729460; called by muse, mutect2, varscan2
- NFRKB | c.571C>T p.R191C (on ENST00000446488 / NM_001143835.2; = p.R204C on NM_006165.3) | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756832085, COSV58760330; called by muse, mutect2, varscan2
- NFX1 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 122/274 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV59313230; called by muse, mutect2, varscan2
- NGEF | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs1487508374, COSV50952917; called by muse, mutect2, varscan2
1,200 further variants in this file (640 protein-altering or splice-affecting, 520 silent, 40 other) are not listed here.
